Surgical pathology report (de-identified scan), TCGA case TCGA-F1-6875, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site UNC, specimen TCGA-F1-6875-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Case Number : [REDACTED]

CLINICAL INFORMAT

The patient is a [REDACTED] male with gastric cancer undergoes subtotal gastrectomy, and lymph node removal. A frozen section is requested by Dr. from [REDACTED]

FROZEN SECTIONS

FS1: SPLENIC NODULE, BIOPSY - SCLEROTIC NODULE WITH FIBROUS CONNECTIVE TISSUE

- NO TUMOR SEEN

Drs..

Anatomic relationships noted at the time of frozen section:

FS1: 0.5 x 0.3 x 0.2, fragment of soft tan tissue with smooth surface.

FS1, NTR. Main tumor 3 cm. from wide (proximal) margin, tumor dimensions 5 x 4 x 2 cm., a portion sheared from the top of the tumor for tumor bank.

GROSS DESCRIPTIONS

(Gross dictation by: [REDACTED])

Four formalin-filled cassettes received each labeled with the patient's name and MR#.

Container #1 is additionally labeled "splenic nodules", and holds a single cassette which is submitted.

Container #2 is additionally labeled "portal nodes", and holds two fragments of yellow/tan moderately firm fibrous tissue measuring 1.2 x 1 x 0.4 cm. in aggregate which are entirely submitted as per block summary.

Container #3 is additionally labeled "spleen", and holds a spleen which weighs 94 gms. and measures 9 x 5.5 x 3.8 cm. The external capsule is intact, cut surfaces show normal splenic parenchyma with no mass lesions identified. Representative sections are submitted as per block summary.

Container #4 is additionally labeled "subtotal gastrectomy", and holds a portion of stomach measuring 14.5 x 9 x 0.8 cm. with attached perigastric fat and mesentery. The external surface of the stomach is largely obscured by fat and mesentery, no mass lesions are identified grossly. The mucosal surface is remarkable for a polypoid mass which measures 4 x 5 x 2 cm. The proximal margin of the mass is 6.5 cm. from the proximal surgical margin, the distal edge of the mass is 3.5 cm. from the distal surgical margin. Cut sections show a polypoid mass

[page 2 of 3]
composed of uniform, light tan tissue with apparent involvement of the underlying muscle wall and no hemorrhagic or necrotic foci identified. Attached mesentery measures 15 x 8 x 4.5 cm. and consists primarily of pale yellow adipose tissue with scattered gray/white fibrous tissue. No mass lesions are identified grossly, representative sections are submitted as per block summary.

BLOCK SUMMARY

- 1 - portal nodes
- 2-4 - spleen
- 5 - stomach, proximal surgical margin
- 6 - normal mucosa, proximal to tumor
- 7 - proximal edge of tumor
- 8-11 - tumor
- 12 - distal edge of tumor
- 13 - inked margin deep to tumor
- 14 - distal mucosa
- 15 - distal surgical margin
- 16-20 - lymph nodes, at tumor
- 21-23 - lymph nodes, proximal to tumor
- 24&25 - lymph nodes, distal to tumor

LIGHT MICROSCOPY

Light microscopic examination is performed.

SPECIAL STUDIES

IMMUNOHISTOCHEMISTRY:

Immunohistochemical stains for synaptophysin are performed on a section of tumor. No significant staining of neoplastic cells is seen.

Accompanying and internal controls stain appropriately.

DIAGNOSIS

STOMACH, ANTRUM, PARTIAL REMOVAL - INVASIVE MODERATELY
DIFFERENTIATED

ADENOCARCINOMA

- TUMOR INVADES INTO BUT NOT THROUGH
MUSCULARIS PROPRIA
- FINAL SURGICAL MARGINS FREE OF
INVOLVEMENT
- NO DEFINITIVE LYMPHOVASCULAR SPACE
INVASION IDENTIFIED

[page 3 of 3]
- GASTRIC ATROPHY WITH EXTENSIVE
INTESTIONAL METAPLASIA
LYMPH NODES, GASTRIC, AT TUMOR, REMOVAL - NO CARCINOMA
IDENTIFIED IN ELEVEN
LYMPH NODES (0/11)
LYMPH NODES, GASTRIC, PROXIMAL TO TUMOR, REMOVAL - NO CARCINOMA
IDENTIFIED
IN FOUR LYMPH NODES (0/4)
LYMPH NODES, GASTRIC, PROXIMAL TO TUMOR, REMOVAL - ADIPOSE
TISSUE, NO LYMPH
NODES IDENTIFIED
LYMPH NODES, PORTAL, REMOVAL - NO CARCINOMA IDENTIFIED IN TWO
LYMPH NODES
(0/2)
NODULE, SPLENIC, REMOVAL - CONSISTENT WITH ACCESSORY SPLEEN
SPLEEN, REMOVAL - NO SIGNIFICANT PATHOLOGICAL ABNORMALITIES

Source: NCI Genomic Data Commons file 75299798-d668-427e-9563-021b3bc96180 (TCGA-F1-6875.D87E2373-341E-47BE-86AF-102C540D8F00.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).